Somatic mutation profile of tumor specimen TARGET-10-PAPZPZ-09A (aliquot TARGET-10-PAPZPZ-09A-01D) from TARGET case TARGET-10-PAPZPZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,232 days).
Specimen TARGET-10-PAPZPZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9d8c924-12ef-4bed-9050-2776d582a776.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPZPZ-10A (Blood Derived Normal), aliquot TARGET-10-PAPZPZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb3d76f9-449a-4471-81e8-80b872ad9671

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, Intron 2, Nonsense Mutation 1, Frame Shift Ins 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4427C>T p.P1476L | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52113088, COSV52117573; called by muse, mutect2
- CREBBP | c.4426C>T p.P1476S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CD084712; called by muse, mutect2, varscan2
- FRAS1 | c.3772G>A p.D1258N | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs191708904; called by muse, mutect2
- NFS1 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.175); catalogued as rs149205059; called by muse, mutect2, varscan2
- RP1 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.072); catalogued as COSV55121175; called by muse, mutect2
- SMARCA5 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs751142387, COSV51647785, COSV99303436; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3742A>G p.I1248V | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRB3 | c.3181A>T p.R1061* | Nonsense Mutation (SNP) | VAF 31/156 reads (20%) | called by muse, mutect2, varscan2
- CADM1 | c.537G>T p.W179C | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM126A | c.971_973delinsACGCGGTTGGA p.G324Dfs*15 | Frame Shift Ins (INS) | VAF 15/65 reads (23%) | called by pindel, varscan2*
- SMG1 | c.7387T>C p.F2463L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ADGRF4 | c.903C>T p.I301= | Silent (SNP) | VAF 30/105 reads (29%) | catalogued as rs768897472; called by muse, mutect2, varscan2
- ADGRF4 | c.904C>T p.L302= | Silent (SNP) | VAF 30/107 reads (28%) | called by muse, mutect2, varscan2
- SLC25A31 | c.48C>T p.D16= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as rs761883245, COSV55418278; called by muse, mutect2, varscan2
- COL1A1 | c.1669-18C>T | Intron (SNP) | VAF 12/58 reads (21%) | catalogued as rs768091337; called by muse, mutect2, varscan2
- IGHV2-70 | chr14:106770576 ins GGTTCCT | 3'Flank (INS) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- OR4H12P | n.47G>A | RNA (SNP) | VAF 17/123 reads (14%) | catalogued as rs1324228916; called by muse, mutect2, varscan2
- ST3GAL3 | c.603-10C>T | Intron (SNP) | VAF 25/74 reads (34%) | catalogued as rs1034450598; called by muse, mutect2, varscan2
